Somatic mutation profile of tumor specimen TCGA-FU-A3HY-01A (aliquot TCGA-FU-A3HY-01A-11D-A21Q-09) from TCGA case TCGA-FU-A3HY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 47.2 years (17,228 days).
Specimen TCGA-FU-A3HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30337043-0808-4e04-803a-78c21d0dc18a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3HY-10A (Blood Derived Normal), aliquot TCGA-FU-A3HY-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e077c21-910c-4aee-8e2e-cc0c4c52a721

The open-access MAF lists 198 somatic variants for this specimen: 141 protein-altering or splice-affecting, 53 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 53, Nonsense Mutation 8, Intron 2, Splice Region 2, RNA 2, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.3658C>T p.Q1220* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as rs886037707, COSV58626917; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.6394G>C p.E2132Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM156165, COSV64672641, COSV64677219; called by muse, mutect2, varscan2
- ABCC1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs753693807, COSV60692990; called by muse, mutect2, varscan2
- ABHD10 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV56326136; called by muse, mutect2, varscan2
- ADAMTS3 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs780251054, CM142272, COSV54400808; called by muse, mutect2, varscan2
- AFF3 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV57856962, COSV57870376; called by muse, mutect2, varscan2
- AFF4 | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as COSV54793110, COSV54799083; called by muse, mutect2, varscan2
- AGPS | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51563218; called by muse, mutect2, varscan2
- ALMS1 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs776916442, COSV100042003, COSV52520271; called by muse, mutect2, varscan2
- APOBR | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs756425975, COSV60493562; called by muse, mutect2, varscan2
- ASAP1 | c.2921A>G p.K974R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV63053723; called by muse, mutect2, varscan2
- ASIC2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56759742, COSV56769104; called by muse, mutect2, varscan2
- AURKA | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV57168987; called by muse, varscan2
- BMI1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV64959625; called by muse, mutect2, varscan2
- BMPR2 | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV65810379, COSV65813082; called by muse, mutect2, varscan2
- BOD1L1 | c.2021G>C p.R674T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV50052327; called by muse, mutect2, varscan2
- C5orf22 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57599848; called by muse, mutect2, varscan2
- CCDC87 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs762152279, COSV100040021; called by muse, mutect2
- CDH18 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV56919829, COSV99935507; called by muse, mutect2
- CECR2 | c.3967A>G p.N1323D (on ENST00000342247 / NM_001290047.2; = p.N1139D on NM_001290046.1) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52847218; called by muse, mutect2, varscan2
- CELA3A | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV51586619; called by muse, mutect2, varscan2
- CEMIP2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs776808520, COSV100987401; called by muse, mutect2, varscan2
- CEP89 | c.2335C>T p.H779Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759032645, COSV59867254; called by muse, mutect2, varscan2
- CNTLN | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as COSV52094202; called by muse, mutect2, varscan2
- COX6A1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs1260503258, COSV57569707; called by muse, mutect2, varscan2
- CSMD1 | c.2101C>T p.P701S (on ENST00000520002; = p.P700S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868531788, COSV59374507; called by muse, mutect2, varscan2
- CSMD1 | c.1657G>C p.E553Q (on ENST00000520002; = p.E552Q on NM_033225.6) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs746010384, COSV59374524; called by muse, mutect2
- DCDC1 | c.3629G>A p.R1210H (on ENST00000597505 / NM_001367979.1; = p.R317H on NM_020869.3) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1386534594, COSV60311782; called by muse, mutect2, varscan2
- DDR2 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV63373891; called by muse, mutect2, varscan2
- DEPDC5 | c.786G>C p.E262D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56709091; called by muse, mutect2
- DGKB | c.2247G>A p.R749= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as COSV51814082; called by muse, mutect2
- DIP2B | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1565865732, COSV56590945; called by muse, mutect2, varscan2
- DIS3 | c.1755G>A p.K585= | Splice Region (SNP) | VAF 16/74 reads (22%) | catalogued as rs1169463352, COSV66707794; called by muse, mutect2, varscan2
- DNAH2 | c.4905C>A p.F1635L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV66722012; called by muse, mutect2, varscan2
- DNAJB14 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62035755; called by muse, mutect2, varscan2
- DNAJC13 | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as COSV53456906; called by muse, mutect2
- DNAJC16 | c.39G>C p.L13F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV61601856; called by muse, mutect2, varscan2
- DPYSL5 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV56515655; called by muse, mutect2, varscan2
- EFL1 | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51609403; called by muse, mutect2, varscan2
- EHD3 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV59032702; called by muse, mutect2, varscan2
- ELL3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.179); catalogued as COSV55858047; called by muse, mutect2, varscan2
- EML5 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747977039, COSV61351457; called by muse, mutect2, varscan2
- ENPP3 | c.1120+1G>T p.X374_splice | Splice Site (SNP) | VAF 14/31 reads (45%) | catalogued as COSV62956267; called by muse, mutect2, varscan2
- EP300 | c.4742C>T p.S1581L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54343512; called by muse, mutect2
- EPB41L3 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs368913981; called by muse, mutect2, varscan2
- EXOC4 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.023); catalogued as COSV54118103; called by muse, mutect2, varscan2
- EXOSC3 | c.807C>G p.F269L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53051244; called by muse, mutect2, varscan2
- EXOSC5 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771048778, COSV54199443; called by muse, mutect2, varscan2
- FAM135B | c.945G>C p.M315I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV52749500; called by muse, mutect2, varscan2
- FBXO22 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57618733; called by muse, mutect2, varscan2
- FLRT1 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.116); catalogued as COSV55357248, COSV55366487; called by muse, mutect2
- FMO2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV52947859; called by muse, mutect2, varscan2
- GSDMD | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV52796587; called by muse, mutect2
- GTF3C1 | c.1202G>C p.R401T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62244447; called by muse, mutect2, varscan2
- HMGN5 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs777711096, COSV63918184; called by muse, mutect2, varscan2
- HNRNPR | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV56423943; called by muse, mutect2, varscan2
- IGKV1-17 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 108/146 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs367999041; called by muse, varscan2
- IMPG2 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV51984071, COSV51984524; called by muse, mutect2, varscan2
- INO80B | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51971404; called by muse, mutect2
- IRF1 | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55378325, COSV99810854; called by muse, mutect2, varscan2
- ITIH2 | c.2714G>A p.R905K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV64432840; called by muse, mutect2
- ITPR1 | c.7697G>C p.R2566T (on ENST00000354582; = p.R2511T on NM_002222.7) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57000977; called by muse, mutect2, varscan2
- KLHL4 | c.1853T>A p.F618Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV64147109; called by muse, mutect2, varscan2
- KPNA2 | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100388787; called by muse, mutect2
- LAMB4 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV52729223; called by muse, mutect2, varscan2
- LMOD2 | c.1437G>C p.K479N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs78874923, COSV71755820, COSV71755864; called by muse, mutect2
- LONP2 | c.2375G>C p.R792T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763867942, COSV53525664; called by muse, mutect2, varscan2
- LRRC19 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV66259783; called by muse, mutect2, varscan2
- LRRFIP1 | c.645G>C p.E215D (on ENST00000392000 / NM_001137552.2; = p.E191D on NM_004735.4) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV55256142; called by muse, mutect2
- MAP3K21 | c.1503G>C p.K501N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1320881896, COSV100786316, COSV64046319; called by muse, mutect2, varscan2
- MAP3K5 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV62891680; called by muse, mutect2, varscan2
- MAPKBP1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as COSV52966498; called by muse, mutect2, varscan2
- MC3R | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54764823; called by muse, mutect2, varscan2
- MID2 | c.251C>G p.S84W | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV53313255; called by muse, mutect2, varscan2
- MS4A6A | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV100125150, COSV60620558, COSV60621551; called by muse, mutect2
- MUC16 | c.8855C>G p.S2952* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV67489086; called by muse, mutect2, varscan2
- MYBPC1 | c.413G>A p.G138E (on ENST00000550270 / NM_206820.2; = p.G163E on NM_002465.4) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62251804; called by muse, mutect2, varscan2
- NAV2 | c.2747C>A p.T916N (on ENST00000396087 / NM_001244963.2; = p.T893N on NM_145117.5) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756161680, COSV62333171; called by muse, mutect2, varscan2
- NEB | c.11816G>C p.R3939T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV51454619; called by muse, mutect2, varscan2
- NEDD4L | c.1951G>C p.E651Q (on ENST00000400345 / NM_001144967.3; = p.E631Q on NM_015277.6) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56852167; called by muse, mutect2, varscan2
- NID1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV51627790; called by muse, mutect2, varscan2
- NIF3L1 | c.829C>T p.H277Y (on ENST00000409020 / NM_001369444.1; = p.H250Y on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV62900568, COSV62900964; called by muse, mutect2
- NLRP14 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as rs958945155, COSV55065779; called by muse, mutect2, varscan2
- NOP2 | c.2059G>A p.E687K (on ENST00000322166 / NM_001258308.2; = p.E683K on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs781331024, COSV59112726; called by muse, mutect2, varscan2
- NXF1 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs891877381, COSV53673798, COSV53676237; called by muse, mutect2, varscan2
- OBSL1 | c.4924G>A p.E1642K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs762255736, COSV54705290; called by muse, mutect2
- OR4K1 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV53462164; called by muse, mutect2, varscan2
- OR6K3 | c.464G>A p.R155Q (on ENST00000368146; = p.R139Q on NM_001005327.2) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as rs1558014670, COSV63745708, COSV63746370; called by muse, mutect2, varscan2
- OR8I2 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV56170099; called by muse, mutect2, varscan2
- PCDHB4 | c.550C>G p.H184D | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV52025392, COSV52026321; called by muse, mutect2, varscan2
- PDILT | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV56704707; called by muse, mutect2
- PFDN2 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs772160399, COSV63510501, COSV63510623; called by muse, mutect2, varscan2
- PHRF1 | c.1289C>G p.S430C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52761862; called by muse, mutect2, varscan2
- PPFIA2 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV61050924; called by muse, mutect2, varscan2
- PPL | c.3007G>C p.D1003H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567986685, COSV52167927; called by muse, mutect2, varscan2
- PYM1 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV56812855; called by muse, mutect2, varscan2
- RAPGEF2 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs966442389, COSV52430408; called by muse, mutect2, varscan2
- RCOR1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.39); catalogued as COSV51771950; called by muse, mutect2
- RIMS1 | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs753621011, COSV53451648, COSV53479703; called by muse, mutect2, varscan2
- RIT1 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs777167776, COSV64171833; called by muse, mutect2, varscan2
- RPL9 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV54695471, COSV54696781; called by muse, mutect2, varscan2
- SDHB | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.428); catalogued as COSV64965688; called by muse, mutect2, varscan2
- SEC24C | c.2056G>C p.E686Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV59544620; called by muse, mutect2, varscan2
- SENP1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50304824; called by muse, mutect2, varscan2
- SERAC1 | c.1324G>C p.D442H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65597706; called by muse, mutect2
- SERPINA10 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56229530; called by muse, mutect2, varscan2
- SH3YL1 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 39/77 reads (51%) | catalogued as rs186175944, COSV62157791; called by muse, mutect2, varscan2
- SHANK2 | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs781885659, COSV53615947; called by muse, mutect2, varscan2
- SLC6A20 | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.529); catalogued as COSV62072520; called by muse, mutect2, varscan2
- SLIT1 | c.3143C>G p.S1048C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV56597589; called by muse, mutect2, varscan2
- SNRNP48 | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV60940652; called by muse, mutect2
- SOX5 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV58634343, COSV58646002; called by muse, mutect2, varscan2
- SPEF2 | c.5433G>C p.E1811D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57431932, COSV57432728; called by muse, mutect2, varscan2
- STEAP4 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as rs749073411, COSV57329325, COSV57331130; called by muse, mutect2, varscan2
- STX1B | c.318C>G p.N106K | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV53062124; called by muse, mutect2, varscan2
- TEP1 | c.4531G>C p.E1511Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52998184, COSV52998948; called by muse, mutect2, varscan2
- TNIK | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs768088861, COSV52692909; called by muse, mutect2, varscan2
- TSHZ1 | c.2480C>T p.S827L (on ENST00000580243 / NM_001308210.2; = p.S782L on NM_005786.6) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1272925884, COSV59005830; called by muse, mutect2, varscan2
- TTC3 | c.2763C>G p.F921L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61295223; called by muse, varscan2
- TTC3 | c.2979C>G p.F993L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100696033, COSV61285136; called by muse, varscan2
- TTN | c.26066C>T p.S8689F (on ENST00000591111; = p.S7762F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | PolyPhen benign (0.027); catalogued as COSV60299397; called by muse, mutect2, varscan2
- USP48 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV57613882; called by muse, mutect2
- UTP20 | c.6148G>A p.D2050N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.623); catalogued as COSV55384357; called by muse, mutect2, varscan2
- VAV3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as COSV58390880; called by muse, mutect2, varscan2
- WWC2 | c.1557G>C p.Q519H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.23); catalogued as COSV66716224; called by muse, mutect2, varscan2
- YBEY | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV52444849; called by muse, mutect2, varscan2
- ZC3H12B | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59051022; called by muse, mutect2, varscan2
- ZFP90 | c.1562G>C p.G521A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68051288; called by muse, mutect2, varscan2
- ZIC1 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51555785, COSV51557609; called by muse, mutect2, varscan2
- ZIC2 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV66255433; called by muse, mutect2, varscan2
- ZNF268 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV57214184; called by muse, mutect2, varscan2
- ZNF536 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750913170, COSV62824867; called by muse, mutect2, varscan2
- ZNF544 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV54136405, COSV54138226; called by muse, mutect2, varscan2
- ZNF571 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as COSV60734509; called by muse, mutect2, varscan2
- ZNF638 | c.1206G>C p.Q402H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52495462; called by muse, mutect2, varscan2
- ZNF740 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1395973866, COSV101407598; called by muse, mutect2, varscan2
- ZRANB2 | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99639425; called by muse, mutect2
- PBRM1 | c.1144del p.V382Ffs*22 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- TTC5 | c.413_415del p.S138del | In Frame Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AADAC | c.834C>T p.F278= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs145358516, COSV51758562, COSV99233259; called by muse, varscan2
- ALDH1A1 | c.777G>A p.G259= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV52791443; called by muse, mutect2
- ANKRD12 | c.1977G>A p.E659= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV50843682; called by muse, mutect2, varscan2
- CACNG7 | c.600C>T p.F200= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV55817004; called by muse, mutect2, varscan2
- CD1D | c.202C>T p.L68= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV63809907; called by muse, mutect2, varscan2
- DAGLA | c.1443C>G p.L481= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV57195752, COSV57199190; called by muse, mutect2, varscan2
- DAPK2 | c.840C>G p.L280= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV56046636; called by muse, mutect2, varscan2
- DCC | c.1476G>A p.L492= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV59130030; called by muse, mutect2, varscan2
- DHX30 | c.849C>G p.L283= (on ENST00000445061 / NM_138615.3; = p.L244= on NM_014966.3) | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs760102603, COSV62394801; called by muse, varscan2
- DNAH5 | c.12669C>T p.F4223= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV54247971; called by muse, mutect2, varscan2
- EBF2 | c.414C>T p.I138= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV68780283; called by muse, mutect2, varscan2
- EME2 | c.615G>A p.P205= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs765979342, COSV51602695; called by muse, mutect2, varscan2
- EMSY | c.2961C>G p.L987= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV58265238; called by muse, mutect2, varscan2
- ETV4 | c.1296C>T p.F432= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs929628730, COSV52256105, COSV99292433; called by muse, mutect2, varscan2
- FBN2 | c.7410C>A p.G2470= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV52541102; called by muse, mutect2, varscan2
- GAS7 | c.603C>T p.C201= (on ENST00000432992 / NM_201433.2; = p.C61= on NM_003644.3) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1238163107, COSV60435467; called by muse, mutect2, varscan2
- GPR155 | c.2427G>A p.L809= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99789940; called by muse, mutect2, varscan2
- GREM2 | c.48G>A p.V16= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV58956435; called by muse, mutect2, varscan2
- HLA-A | c.675G>C p.L225= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV100954382, COSV65140303, COSV65141497; called by muse, varscan2
- HOOK2 | c.1824C>T p.R608= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1382737125, COSV53403850; called by muse, mutect2, varscan2
- IGHV3-7 | c.111G>A p.L37= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs546728538; called by muse, mutect2, varscan2
- ILVBL | c.1695C>T p.N565= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs773383279, COSV54622215; called by muse, mutect2, varscan2
- INHBE | c.543G>A p.E181= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV56988885; called by muse, mutect2, varscan2
- KCNC4 | c.942C>G p.L314= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV100873627; called by muse, mutect2, varscan2
- KDM7A | c.2661C>T p.F887= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs753241969, COSV50095305; called by muse, mutect2, varscan2
- MAGEA6 | c.675G>A p.L225= | Silent (SNP) | VAF 36/179 reads (20%) | catalogued as COSV61449386; called by muse, mutect2, varscan2
- MAPK8IP1 | c.150G>A p.S50= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs190170522, COSV53799495, COSV99571684; called by muse, mutect2, varscan2
- MIB2 | c.2304C>T p.L768= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100598933; called by muse, mutect2, varscan2
- MLH3 | c.1269G>A p.Q423= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV53135788; called by muse, mutect2, varscan2
- NFATC2 | c.1017C>T p.A339= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs774864876, COSV65360330; called by muse, mutect2, varscan2
- NUP98 | c.4656C>T p.Y1552= (on ENST00000359171 / NM_001365126.1; = p.Y1535= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs775540113, COSV61430751; called by muse, mutect2, varscan2
- PJA2 | c.1419T>C p.S473= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1204938243, COSV63274358; called by muse, mutect2, varscan2
- PLS3 | c.1503G>A p.L501= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56781755; called by mutect2, varscan2
- POC1B | c.252G>A p.V84= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV57968260; called by muse, mutect2, varscan2
- RADX | c.2043G>A p.E681= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100998850; called by muse, mutect2
- RBMX2 | c.567C>A p.P189= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV59729827; called by muse, mutect2, varscan2
- RTN4RL2 | c.195C>G p.L65= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV58652180, COSV58652926; called by muse, mutect2, varscan2
- SLC17A8 | c.1620G>T p.A540= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV60126310; called by muse, mutect2, varscan2
- SLC25A2 | c.246C>T p.F82= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV53404781; called by muse, mutect2, varscan2
- SLIT3 | c.1980C>G p.L660= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as COSV60630512; called by muse, mutect2, varscan2
- SNRNP200 | c.5346G>A p.S1782= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs756239767, COSV60493952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA31A1 | c.1867C>T p.L623= | Silent (SNP) | VAF 52/252 reads (21%) | catalogued as rs1253284510; called by muse, mutect2
- SPP1 | c.501G>A p.L167= (on ENST00000395080 / NM_001040058.2; = p.L153= on NM_000582.2) | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs751948923, COSV52952656; called by muse, mutect2, varscan2
- TAPBP | c.321C>T p.S107= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV69668358; called by muse, mutect2
- TMEM161B | c.1071G>A p.T357= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs201032572, COSV56933591; called by muse, mutect2, varscan2
- TMEM94 | c.114C>T p.L38= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV58599349; called by muse, mutect2, varscan2
- TMEM94 | c.216C>T p.L72= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV58599355; called by muse, mutect2, varscan2
- TRIM2 | c.1236C>T p.I412= (on ENST00000437508; = p.I439= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV58638057; called by muse, mutect2, varscan2
- TRPV6 | c.438C>G p.V146= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV63893365; called by muse, mutect2
- TTN | c.56676G>A p.E18892= (on ENST00000591111; = p.E11468= on NM_003319.4) | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100615891; called by muse, mutect2, varscan2
- UBA7 | c.2013G>A p.A671= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs766026076, COSV60968577; called by muse, mutect2, varscan2
- VRTN | c.1428G>A p.K476= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV56443299; called by muse, mutect2, varscan2
- ZNF223 | c.1263C>G p.L421= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV71572098; called by muse, mutect2, varscan2
- INSIG1 | c.804+990C>T | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as COSV60921140; called by muse, mutect2, varscan2
- PIK3C2B | c.934-1643C>T | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as rs774692466; called by muse, mutect2, varscan2
- WASF4P | n.693G>C | RNA (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- XIST | n.8847C>T | RNA (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
